Somatic mutation profile of tumor specimen TCGA-17-Z015-01A (aliquot TCGA-17-Z015-01A-01W-0746-08) from TCGA case TCGA-17-Z015, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b84c03bf-8875-4810-afc9-efb787e1d277.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z015-11A (Solid Tissue Normal), aliquot TCGA-17-Z015-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/835e9665-96ad-4f39-91cd-f996d122bf6a

The open-access MAF lists 533 somatic variants for this specimen: 428 protein-altering or splice-affecting, 98 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 371, Silent 98, Nonsense Mutation 28, Splice Site 10, Frame Shift Del 8, Frame Shift Ins 6, Intron 4, RNA 3, Splice Region 2, Nonstop Mutation 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 90/155 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM21 | c.1434T>A p.N478K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1422153768; called by muse, mutect2
- AHNAK | c.3966G>C p.K1322N | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as rs751942329; called by muse, mutect2, varscan2
- AMER1 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV100365705; called by muse, mutect2, varscan2
- AMHR2 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs757385870; called by muse, mutect2, varscan2
- ANK2 | c.9050C>A p.P3017H | Missense Mutation (SNP) | VAF 47/359 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV52147100; called by muse, mutect2, varscan2
- ARAP2 | c.60G>C p.L20F | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100394550; called by muse, mutect2, varscan2
- ARID3C | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as rs1159256703, COSV52407516; called by muse, mutect2, varscan2
- ASB15 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 23/187 reads (12%) | catalogued as rs1404075406, COSV51928838; called by muse, mutect2, varscan2
- ASTN2 | c.2202C>A p.F734L (on ENST00000313400 / NM_001365069.1; = p.F683L on NM_014010.5) | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs1350221066; called by muse, mutect2, varscan2
- ATG2B | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as rs962889054; called by muse, mutect2, varscan2
- AWAT1 | c.254C>A p.T85K | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65738124, COSV65738782; called by muse, mutect2, varscan2
- BACE2 | c.1502G>T p.R501L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as COSV57739787, COSV57742038; called by muse, varscan2
- BRWD3 | c.4601A>G p.H1534R | Missense Mutation (SNP) | VAF 129/348 reads (37%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); catalogued as rs772280598; called by muse, varscan2
- C6orf118 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.74); PolyPhen benign (0.08); catalogued as COSV57814483, COSV57816483; called by muse, mutect2, varscan2
- CARF | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1195486976; called by muse, mutect2
- CCL28 | c.65-1G>T p.X22_splice | Splice Site (SNP) | VAF 16/31 reads (52%) | catalogued as rs78470036; called by muse, varscan2
- CCNB3 | c.3670C>A p.R1224S | Missense Mutation (SNP) | VAF 172/257 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV52070254; called by muse, mutect2, varscan2
- CFAP65 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs754175652; called by muse, mutect2, varscan2
- CFAP70 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs761035849, COSV100160807, COSV60285382; called by muse, mutect2, varscan2
- CHRM3 | c.1655G>T p.R552I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1336414257; called by muse, mutect2, varscan2
- CHRND | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV99285658; called by muse, mutect2, varscan2
- CLEC7A | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as rs1202837056, COSV53722604; called by muse, mutect2, varscan2
- CLSTN1 | c.523G>A p.E175K (on ENST00000377298 / NM_001009566.3; = p.E165K on NM_014944.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1382854238, COSV100790615; called by muse, mutect2, varscan2
- CMA1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1429605331, COSV99157266; called by muse, mutect2, varscan2
- CMKLR1 | c.110G>T p.R37M (on ENST00000312143 / NM_001142344.2; = p.R35M on NM_004072.3) | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs1222269580; called by muse, mutect2, varscan2
- CNBD1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs751448210; called by muse, mutect2, varscan2
- COL11A1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs543199135, COSV100618142; called by muse, mutect2, varscan2
- COL19A1 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1562104949; called by muse, mutect2, varscan2
- CPS1 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.231); catalogued as COSV99241238; called by muse, mutect2, varscan2
- CSN3 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1310333338; called by muse, mutect2, varscan2
- CST9 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV65402478; called by muse, varscan2
- CYLC1 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1200879157; called by muse, mutect2, varscan2
- DBH | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV55039865; called by muse, mutect2, varscan2
- DCAF4L2 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60477561; called by muse, mutect2, varscan2
- DCAF6 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372667122; called by muse, mutect2, varscan2
- DCSTAMP | c.322T>A p.L108M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as COSV52577403; called by muse, mutect2, varscan2
- DDIAS | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as rs761510889, COSV61271890; called by muse, mutect2, varscan2
- DIO2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1259641253, COSV70445819; called by muse, mutect2, varscan2
- DLG5 | c.3373C>A p.P1125T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1250360300, COSV64947669; called by muse, varscan2
- DPY19L2 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.019); catalogued as COSV60542517; called by muse, mutect2, varscan2
- DSP | c.6043G>A p.A2015T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs1200353349; called by muse, mutect2, varscan2
- DYNC1H1 | c.10876G>T p.A3626S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs1414585001, COSV64139823; called by muse, mutect2, varscan2
- EPHA5 | c.2415C>A p.N805K | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV99897780; called by muse, mutect2, varscan2
- EPHA7 | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV100993297; called by muse, mutect2, varscan2
- EPHB1 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs559321367; called by muse, mutect2, varscan2
- ETV5 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs767971453; called by muse, mutect2, varscan2
- EVX2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57962662; called by muse, mutect2, varscan2
- F10 | c.680G>T p.R227M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1048223186; called by muse, mutect2, varscan2
- FAM114A2 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 37/75 reads (49%) | catalogued as rs1490781226; called by muse, mutect2, varscan2
- FCHSD2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.04); catalogued as rs569167163, COSV60807639; called by muse, mutect2, varscan2
- FCRL6 | c.858G>C p.R286S | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV58942746; called by muse, mutect2, varscan2
- FGFR4 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34158682, COSV52802564; called by muse, mutect2, varscan2
- FLG | c.11842G>T p.G3948C | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV64242392; called by muse, mutect2, varscan2
- FLG | c.7754G>T p.G2585V | Missense Mutation (SNP) | VAF 107/274 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as rs530189443; called by muse, mutect2, varscan2
- FLG | c.7753G>T p.G2585W | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100911637; called by muse, mutect2, varscan2
- FOXR1 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 51/140 reads (36%) | catalogued as rs1343756854; called by muse, mutect2, varscan2
- FXN | c.313G>A p.V105M (on ENST00000377270; = p.V180M on NM_000144.5) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as rs774482038; called by muse, mutect2, varscan2
- FZD4 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776026462, COSV72294363; called by muse, mutect2, varscan2
- GABRQ | c.946C>G p.R316G | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64780814; called by muse, mutect2, varscan2
- GALNT13 | c.912G>T p.E304D | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV67216224; called by muse, mutect2, varscan2
- GGT7 | c.1093G>T p.V365L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV60540487; called by muse, mutect2
- GIMAP1 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 186/477 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs777141777; called by muse, mutect2, varscan2
- GPR174 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV52133204; called by muse, mutect2, varscan2
- GPRIN1 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1324365565; called by muse, mutect2, varscan2
- GRIN3A | c.2192C>A p.T731K | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199739902; called by muse, mutect2, varscan2
- GRK5 | c.1341del p.F448Sfs*4 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as COSV64866052; called by mutect2, varscan2
- GRM1 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV51152723, COSV99268008; called by muse, mutect2, varscan2
- H2AP | c.291C>G p.S97R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV61910780; called by muse, mutect2, varscan2
- H4C4 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs573032310, COSV61591809; called by muse, mutect2, varscan2
- HIPK2 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1442542662, COSV100702689; called by muse, mutect2, varscan2
- HLTF | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs371233960, COSV104402048; called by muse, mutect2, varscan2
- HOXA3 | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.058); catalogued as COSV57825913; called by muse, mutect2, varscan2
- HOXD13 | c.308del p.P103Qfs*163 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | catalogued as rs1480246716; called by mutect2, varscan2
- HTR5A | c.1016C>G p.T339R | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773555483, COSV55283534; called by muse, mutect2, varscan2
- IGF2BP1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs751061699, COSV99288337; called by muse, mutect2, varscan2
- IQCJ | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1436503993; called by muse, mutect2, varscan2
- KAT6B | c.3404G>A p.R1135H | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138617006, COSV54741411; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNH4 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs201093626, COSV52921288; called by muse, mutect2, varscan2
- KCNN3 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1326312153, COSV99679595; called by muse, mutect2
- LGR6 | c.2624A>T p.D875V (on ENST00000367278 / NM_001017403.1; = p.D823V on NM_021636.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs373576054; called by muse, mutect2, varscan2
- LRFN2 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as COSV100599540; called by muse, mutect2, varscan2
- MAGEA3 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV64755941; called by muse, mutect2
- MAP3K9 | c.2381G>T p.R794L (on ENST00000554752 / NM_001284230.1; = p.R808L on NM_033141.4) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as COSV101173656, COSV67120956; called by muse, mutect2, varscan2
- MARK1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 47/216 reads (22%) | catalogued as rs1322940585, COSV65071055; called by muse, mutect2, varscan2
- ME3 | c.1483G>C p.G495R | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62772520; called by muse, mutect2, varscan2
- MMP27 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.181); catalogued as rs779108579; called by muse, mutect2, varscan2
- MUC16 | c.12805T>C p.S4269P | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as rs778004227; called by muse, mutect2
- MUC17 | c.7898C>G p.T2633S | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV60292354; called by muse, mutect2, varscan2
- MYO18B | c.2321T>A p.L774Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476325875; called by muse, mutect2, varscan2
- NEB | c.5074G>A p.G1692S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764638678; called by muse, mutect2, varscan2
- NEB | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.524); catalogued as rs765478068, COSV51432733; called by muse, mutect2, varscan2
- NF1 | c.3479del p.G1160Vfs*6 | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | catalogued as COSV62213039; called by mutect2, pindel, varscan2
- NF1 | c.5416C>T p.Q1806* (on ENST00000358273 / NM_001042492.3; = p.Q1785* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 48/149 reads (32%) | catalogued as CM000812, COSV62216526; called by muse, mutect2, varscan2
- NONO | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV52137355; called by muse, mutect2, varscan2
- NRIP1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs553224991, COSV59659321; called by muse, mutect2, varscan2
- NUTM1 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1042643515; called by muse, mutect2, varscan2
- OR10Z1 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 77/605 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs186326508; called by muse, mutect2, varscan2
- OR2C3 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV63576865; called by mutect2, varscan2
- OR2M7 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 102/329 reads (31%) | catalogued as rs1292491932, COSV58738981; called by muse, mutect2, varscan2
- OR4M1 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 108/387 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747720585, COSV100271251; called by muse, mutect2, varscan2
- OR5AN1 | c.920A>G p.K307R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV58322395; called by muse, mutect2, varscan2
- OR5P2 | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1357080508, COSV61490183; called by muse, mutect2, varscan2
- OR6C2 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 134/198 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV59516568; called by muse, mutect2, varscan2
- OR8K5 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV100537170; called by muse, mutect2
- OSR2 | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs764701063, COSV52556072; called by muse, mutect2, varscan2
- PABPC5 | c.295C>A p.R99S | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.116); catalogued as COSV57038886, COSV57041705; called by muse, mutect2, varscan2
- PCDH11X | c.12G>T p.L4F | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs144734965, COSV53503929; called by muse, mutect2, varscan2
- PCDH11X | c.2359C>A p.R787S | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.626); catalogued as COSV53462682; called by muse, mutect2, varscan2
- PCDHA1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as rs782403534, COSV65375073; called by muse, mutect2, varscan2
- PCDHA6 | c.946T>C p.Y316H | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.399); catalogued as rs782434715, COSV65350739; called by muse, mutect2, varscan2
- PCDHA8 | c.1295C>G p.S432W | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65334825; called by muse, mutect2, varscan2
- PCDHB2 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99167022; called by muse, mutect2, varscan2
- PCDHGA8 | c.1282G>T p.G428* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV54049903, COSV99548592; called by muse, mutect2, varscan2
- PCLO | c.12349G>C p.D4117H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61665488; called by muse, mutect2, varscan2
- PCMTD1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV62121706; called by muse, mutect2, varscan2
- PDZD2 | c.2384A>G p.H795R | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV56861606; called by muse, mutect2, varscan2
- PFKFB1 | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | PolyPhen benign (0.1); catalogued as COSV100895648; called by muse, mutect2, varscan2
- PGS1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749520109; called by muse, mutect2, varscan2
- PIWIL4 | c.2030G>T p.W677L | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1275078870; called by muse, mutect2, varscan2
- PLEKHA6 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1345456251; called by muse, mutect2, varscan2
- PLEKHG7 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs771023819, COSV60822947; called by muse, mutect2, varscan2
- PLK4 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs200955595; called by muse, mutect2, varscan2
- PLXNA4 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV58107782; called by muse, mutect2, varscan2
- POTEE | c.2496G>T p.M832I | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as rs1404653705; called by muse, mutect2, varscan2
- PPARD | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as rs1181758701, COSV61099221; called by muse, mutect2, varscan2
- PPP1R32 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.939); catalogued as rs1245419578; called by muse, mutect2, varscan2
- PPP3CA | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59921756; called by muse, mutect2, varscan2
- PRAMEF4 | c.1161C>A p.F387L | Missense Mutation (SNP) | VAF 162/371 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.05); catalogued as rs1440866467, COSV52441102; called by muse, mutect2, varscan2
- PRDM10 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100456924; called by muse, mutect2, varscan2
- PTPRZ1 | c.6084+1G>T p.X2028_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | catalogued as rs867866342; called by muse, mutect2, varscan2
- PXDNL | c.3014T>A p.V1005E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1304190524; called by muse, mutect2, varscan2
- RAB6B | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1020325020; called by muse, mutect2, varscan2
- RBBP6 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); catalogued as rs1380945532, COSV60508320; called by muse, mutect2, varscan2
- RETREG1 | c.1322C>A p.P441H (on ENST00000306320 / NM_001034850.2; = p.P300H on NM_019000.4) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV60451141; called by muse, mutect2, varscan2
- RFTN2 | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV99695520; called by muse, mutect2, varscan2
- RHBDF1 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs780544930; called by muse, mutect2
- RPL10L | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 22/119 reads (18%) | catalogued as COSV53558471; called by muse, mutect2, varscan2
- RREB1 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs1490387840, COSV58567528; called by muse, mutect2, varscan2
- SALL1 | c.3259A>G p.T1087A | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.042); catalogued as COSV51760930; called by muse, mutect2, varscan2
- SERPINE2 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs759587862, COSV51458095; called by muse, mutect2, varscan2
- SEZ6L2 | c.485C>A p.T162N (on ENST00000308713 / NM_001114099.3; = p.T92N on NM_012410.4) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1438319984; called by muse, mutect2, varscan2
- SIPA1L2 | c.3361C>A p.P1121T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs1176284004; called by muse, mutect2, varscan2
- SIRPD | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101064934; called by muse, mutect2, varscan2
- SLC35B3 | c.985+1G>T p.X329_splice | Splice Site (SNP) | VAF 34/94 reads (36%) | catalogued as rs1448814237; called by muse, varscan2
- SLC38A6 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569309544; called by muse, mutect2, varscan2
- SLC6A19 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.236); catalogued as rs894693588, COSV100443598; called by muse, mutect2
- SMIM14 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254117701; called by muse, mutect2, varscan2
- SNAP91 | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771926128; called by muse, mutect2, varscan2
- SPICE1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.542); catalogued as rs755208230; called by muse, varscan2
- ST3GAL2 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | PolyPhen benign (0.145); catalogued as rs574593500, COSV100735684; called by muse, mutect2, varscan2
- ST3GAL2 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | PolyPhen possibly damaging (0.857); catalogued as rs758483209, COSV61596730; called by muse, mutect2, varscan2
- STAB2 | c.4883G>T p.G1628V | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386140480; called by muse, mutect2
- STRA6 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs748253525; called by muse, mutect2, varscan2
- TBX22 | c.1214C>A p.P405Q | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV100960895; called by muse, mutect2, varscan2
- TDRD6 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs551757424, COSV60179017; called by muse, mutect2, varscan2
- TMEM31 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 188/698 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs765110784, COSV100128983; called by muse, mutect2, varscan2
- TNRC6A | c.2621G>T p.S874I | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs199866852; called by muse, mutect2, varscan2
- TOR3A | c.1159T>A p.S387T | Missense Mutation (SNP) | VAF 67/392 reads (17%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.935); catalogued as COSV100751258; called by muse, mutect2, varscan2
- TOX | c.563G>A p.S188N | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV63850301; called by muse, mutect2, varscan2
- TRPC4 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1292028960; called by muse, mutect2, varscan2
- TSHZ3 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs1164252025, COSV53663731; called by muse, mutect2, varscan2
- UBQLN4 | c.1616A>T p.Q539L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1391932847; called by muse, mutect2, varscan2
- UNC79 | c.5566T>C p.S1856P (on ENST00000393151 / NM_001346218.2; = p.S1679P on NM_020818.5) | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.244); catalogued as rs1402159149, COSV56383285; called by muse, mutect2, varscan2
- URGCP | c.2737G>A p.G913S (on ENST00000453200 / NM_001077663.3; = p.G904S on NM_017920.4) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.947); catalogued as rs775817971; called by muse, mutect2, varscan2
- USHBP1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs769889239, COSV99394377; called by muse, mutect2, varscan2
- ZC3H14 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV51773170; called by muse, mutect2, varscan2
- ZEB1 | c.3067G>C p.D1023H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58041731; called by muse, mutect2, varscan2
- ZFHX4 | c.8469G>T p.M2823I | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.241); catalogued as COSV51498855; called by muse, mutect2, varscan2
- ZNF251 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565210932; called by muse, mutect2, varscan2
- ZNF454 | c.466G>C p.G156R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.78); catalogued as COSV60766624; called by muse, mutect2, varscan2
- ZNF532 | c.3859G>A p.G1287S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350520700; called by muse, varscan2
- ZNF862 | c.3122G>A p.R1041Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs367713222; called by muse, mutect2, varscan2
- ABCB1 | c.2048G>C p.S683T | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABTB2 | c.2252C>G p.S751C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ACOT6 | c.18+1G>C p.X6_splice | Splice Site (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- ADCK1 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADGRB3 | c.4007C>T p.P1336L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRE1 | c.1708C>A p.L570M | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ADGRG4 | c.1475C>A p.P492Q | Missense Mutation (SNP) | VAF 21/763 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2
- ADGRG4 | c.1976G>T p.R659M | Missense Mutation (SNP) | VAF 206/888 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- AGAP4 | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ALDH1B1 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- ANK2 | c.5419C>A p.P1807T | Missense Mutation (SNP) | VAF 154/483 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ANKIB1 | c.1811G>T p.R604I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- AOC1 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ARHGAP32 | c.5993A>G p.E1998G (on ENST00000310343 / NM_001378025.1; = p.E1649G on NM_014715.4) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARMCX3 | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARMCX5 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 110/273 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARSF | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ASXL3 | c.2708A>T p.Q903L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ATP1B4 | c.759G>T p.R253= (on ENST00000218008 / NM_001142447.3; = p.R249= on NM_012069.5) | Splice Region (SNP) | VAF 41/173 reads (24%) | called by muse, mutect2, varscan2
- ATR | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GAT2 | c.881C>A p.T294N | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- B4GALNT2 | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- BAZ1B | c.4030_4041del p.E1344_K1347del | In Frame Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- BRWD3 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- BTN3A3 | c.964C>A p.R322S | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CASP5 | c.720T>C p.D240= | Splice Region (SNP) | VAF 49/106 reads (46%) | called by muse, mutect2, varscan2
- CBLIF | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CC2D1B | c.232C>G p.H78D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); called by mutect2, varscan2
- CCDC13 | c.826-1G>T p.X276_splice | Splice Site (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- CCDC42 | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CCIN | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCT8L2 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CD8B | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42BPA | c.3529T>C p.C1177R (on ENST00000334218 / NM_001366019.2; = p.C1164R on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CDH22 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFL2 | c.139A>T p.I47L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CKMT2 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CLDN17 | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CLHC1 | c.731C>A p.A244E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CLMP | c.1013C>A p.P338Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CLTCL1 | c.2313G>T p.Q771H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLVS2 | c.565-2A>T p.X189_splice | Splice Site (SNP) | VAF 55/106 reads (52%) | called by muse, mutect2, varscan2
- CNTN4 | c.171A>T p.K57N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CNTNAP1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- COBL | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- COL4A5 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A5 | c.4408A>G p.T1470A | Missense Mutation (SNP) | VAF 137/327 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- COL5A2 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL7A1 | c.4223G>C p.R1408P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRP | c.272A>T p.Y91F | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CSMD1 | c.5437A>T p.T1813S (on ENST00000520002; = p.T1812S on NM_033225.6) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CX3CL1 | c.1162G>C p.G388R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCLRE1A | c.1180A>T p.S394C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- DDX25 | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHCR24 | c.1184A>C p.Q395P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DIDO1 | c.651G>T p.Q217H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- DOCK2 | c.4090C>A p.R1364S | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DTNA | c.20A>C p.K7T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DYNC1H1 | c.5936A>G p.Q1979R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDNRB | c.788dup p.M263Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.M173Ifs*3 on NM_000115.5) | Frame Shift Ins (INS) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- ENOSF1 | c.579G>T p.M193I (on ENST00000340116 / NM_001354066.2; = p.M145I on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ENPEP | c.2206G>T p.A736S | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHA10 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHA6 | c.2371G>A p.G791R (on ENST00000389672 / NM_001080448.3; = p.G183R on NM_173655.4) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA7 | c.2029A>G p.R677G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- EXOC3L1 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FABP12 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.127); called by muse, mutect2
- FAM135A | c.4374G>T p.L1458F (on ENST00000370479 / NM_001351599.1; = p.L1245F on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM47A | c.2177A>G p.E726G | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM71B | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FHL1 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 311/614 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FHOD3 | c.2357A>T p.Y786F (on ENST00000359247 / NM_001281739.3; = p.Y803F on NM_025135.5) | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- FLG2 | c.3391C>A p.H1131N | Missense Mutation (SNP) | VAF 111/512 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- FMR1NB | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- FOXL1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FRMPD4 | c.1179G>C p.L393F | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FSTL5 | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAD2 | c.324G>T p.L108F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- GALNT18 | c.128_129insCCC p.G43_Q44insP | In Frame Ins (INS) | VAF 9/20 reads (45%) | called by mutect2, varscan2
- GARNL3 | c.1624G>T p.V542F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GLDC | c.2169G>T p.Q723H | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLE1 | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | called by muse, varscan2
- GLYATL2 | c.249C>G p.D83E | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR141 | c.810G>T p.L270F | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRIA2 | c.2443G>T p.G815* | Nonsense Mutation (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2, varscan2
- GRM8 | c.2320C>A p.P774T | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD2 | c.2021G>C p.R674T | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- HEMGN | c.1361-1G>T p.X454_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- HHIP | c.1019G>T p.R340I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- HTATSF1 | c.1987del p.A663Rfs*114 | Frame Shift Del (DEL) | VAF 181/431 reads (42%) | called by mutect2, pindel, varscan2
- HTR1B | c.1043T>A p.L348Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR5A | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-43 | c.270del p.T91Rfs*? | Frame Shift Del (DEL) | VAF 102/356 reads (29%) | called by mutect2, pindel*, varscan2
- IGKV2D-24 | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- IGKV3D-20 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1943T>A p.L648Q | Missense Mutation (SNP) | VAF 89/210 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- IQSEC2 | c.3202G>T p.D1068Y (on ENST00000642864 / NM_001111125.3; = p.D863Y on NM_015075.2) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IRF4 | c.572del p.P191Rfs*6 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- JAK1 | c.2971del p.M991Wfs*27 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- KASH5 | c.500A>G p.E167G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- KBTBD8 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2
- KCND3 | c.959A>T p.E320V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNJ10 | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 114/288 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by mutect2, varscan2
- KCNK9 | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2
- KCNK9 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.066); called by muse, mutect2
- KCNS2 | c.1322C>A p.S441* | Nonsense Mutation (SNP) | VAF 100/178 reads (56%) | called by muse, mutect2, varscan2
- KCNT2 | c.1739A>C p.H580P | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- KIF6 | c.827C>G p.S276* | Nonsense Mutation (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- KIT | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLHL24 | c.1191A>T p.R397S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT25 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRTAP24-1 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KRTAP9-2 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- LANCL2 | c.695T>A p.I232N | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- LEPROT | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- LMNTD1 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPAR1 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 129/331 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LRP1B | c.1412G>T p.R471I | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- LTB | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.927); called by muse, mutect2
- LYST | c.8222G>C p.R2741P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MAGEA11 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGOH | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAN2B1 | c.2108T>A p.L703Q | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1LC3C | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- MAP3K2 | c.415T>G p.L139V | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAPK8IP1 | c.1839C>G p.I613M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MDN1 | c.2663A>T p.D888V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MECP2 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MKI67 | c.6943G>T p.D2315Y | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MKI67 | c.6941A>G p.E2314G | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MLH3 | c.1934G>A p.R645K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMP7 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- MPP1 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 68/1604 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2
- MSMB | c.143dup p.N49Kfs*7 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- MTA3 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- MYLK3 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- MYO1A | c.469T>A p.S157T | Missense Mutation (SNP) | VAF 80/104 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYO3A | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAIP | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NALCN | c.182T>A p.F61Y | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NCOA6 | c.4375A>G p.K1459E | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- NDP | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NEFL | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NFASC | c.320G>T p.G107V (on ENST00000339876 / NM_001378329.1; = p.G101V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- NFE2L2 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- NKRF | c.1217dup p.L406Ffs*41 | Frame Shift Ins (INS) | VAF 31/89 reads (35%) | called by mutect2, pindel, varscan2
- NLRP1 | c.3583G>C p.E1195Q | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRAP | c.4001G>T p.C1334F (on ENST00000359988 / NM_001322945.2; = p.C1299F on NM_006175.4) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUMA1 | c.6187C>G p.L2063V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NWD1 | c.3163C>A p.Q1055K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.054); called by muse, mutect2
- OGT | c.563C>G p.P188R | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OGT | c.1325C>G p.S442* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- OLFM4 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10W1 | c.536T>G p.V179G | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- OR2B6 | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- OR2T10 | c.212T>A p.L71* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- OR4A15 | c.38T>C p.L13S | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- OR4A16 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR4C11 | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR56A3 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR8B2 | c.135G>T p.L45F | Missense Mutation (SNP) | VAF 52/493 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR8B3 | c.135G>T p.L45F | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OVCH1 | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- P2RY4 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHGB1 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.299); called by muse, varscan2
- PCDHGB1 | c.1730C>A p.A577D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- PDE4A | c.792G>C p.R264S (on ENST00000380702 / NM_001111307.2; = p.R25S on NM_006202.3) | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PEX5L | c.194C>A p.S65* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | called by muse, mutect2, varscan2
- PFKFB1 | c.207A>G p.I69M | Missense Mutation (SNP) | VAF 310/466 reads (67%) | PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- PHF6 | c.698C>G p.A233G (on ENST00000332070 / NM_032458.3; = p.A234G on NM_032335.3) | Missense Mutation (SNP) | VAF 107/241 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PIEZO2 | c.7814T>C p.L2605P | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PJA1 | c.1900G>T p.V634L (on ENST00000361478 / NM_145119.4; = p.V446L on NM_022368.5) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PKP1 | c.255G>T p.R85S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PLA2G7 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- PLB1 | c.1612C>A p.L538M | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB1 | c.695+2T>C p.X232_splice | Splice Site (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- PLXDC2 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLXNA3 | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PLXNA3 | c.4599G>T p.W1533C | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PNMA5 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 13/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POT1 | c.1838C>G p.T613R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEF | c.1576A>T p.N526Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); called by mutect2, varscan2
- PRAMEF1 | c.927C>A p.D309E | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRAMEF15 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PROK2 | c.206dup p.H69Qfs*6 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- PRRC2A | c.5441A>C p.K1814T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PSD3 | c.1723A>T p.S575C | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PTX4 | c.1222G>A p.D408N (on ENST00000447419 / NM_001328608.2; = p.D403N on NM_001013658.1) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RAB6A | c.224T>C p.F75S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- RASA1 | c.1253G>C p.S418T | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- RC3H1 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- RERG | c.216dup p.H73Afs*16 | Frame Shift Ins (INS) | VAF 139/368 reads (38%) | called by mutect2, pindel, varscan2
- RGS4 | c.37T>G p.L13V | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- RHBDF1 | c.853T>A p.S285T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- RIMBP2 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- RLIM | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- SACS | c.2968A>T p.S990C | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- SEMA5A | c.171T>A p.D57E | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINA4 | c.1226C>A p.S409Y | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SETX | c.1484T>C p.L495P | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIRPA | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC13A5 | c.115G>C p.A39P | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC17A2 | c.828G>T p.W276C | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC22A23 | c.1359G>T p.M453I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SLC30A9 | c.1288G>T p.V430L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SLC33A1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC39A12 | c.1566G>C p.M522I (on ENST00000377369 / NM_001145195.2; = p.M485I on NM_152725.3) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC44A5 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A6 | c.1161C>A p.F387L | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SLIT3 | c.2072A>T p.Q691L | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- SLITRK1 | c.1381C>G p.L461V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SPAG9 | c.784-1G>T p.X262_splice (on ENST00000262013 / NM_001130528.3; = p.X248_splice on NM_003971.6) | Splice Site (SNP) | VAF 18/59 reads (31%) | called by muse, varscan2
- SPEF2 | c.4533G>T p.W1511C | Missense Mutation (SNP) | VAF 97/130 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTBN1 | c.512A>G p.E171G | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- STARD3 | c.765G>T p.Q255H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- STOML3 | c.761G>T p.S254I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SVEP1 | c.8963G>C p.R2988T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- TAGLN3 | c.143dup p.R49Qfs*20 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- TATDN1 | c.347-9_351delinsCA p.X116_splice | Splice Site (DEL) | VAF 3/28 reads (11%) | called by muse*, pindel
- THSD7B | c.2841C>G p.H947Q | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIMMDC1 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- TKTL1 | c.740T>A p.L247* | Nonsense Mutation (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2
- TMEM67 | c.541A>T p.S181C | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TMEM86A | c.619G>C p.A207P | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TMEM9 | c.237G>T p.R79S | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNKS2 | c.2791G>C p.E931Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TNN | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- TNR | c.3814C>A p.Q1272K | Missense Mutation (SNP) | VAF 168/578 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TNRC18 | c.6587G>C p.R2196P | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TPM3 | c.338del p.K113Sfs*16 | Frame Shift Del (DEL) | VAF 92/217 reads (42%) | called by mutect2, pindel, varscan2
- TREML4 | c.602G>C p.*201Sext*41 | Nonstop Mutation (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- TRIM43 | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPC1 | c.1990C>G p.R664G (on ENST00000476941 / NM_001251845.2; = p.R630G on NM_003304.4) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- TRPM8 | c.2086A>T p.I696F | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- TUBA3C | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TUBB2B | c.678C>A p.N226K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- UBQLN2 | c.827A>C p.Q276P | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UBR2 | c.2101G>C p.G701R | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UGT3A1 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- UNC5C | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 106/311 reads (34%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UNC79 | c.4308T>A p.H1436Q (on ENST00000393151 / NM_001346218.2; = p.H1259Q on NM_020818.5) | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- URI1 | c.721A>T p.T241S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- VCAN | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VIRMA | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VWCE | c.1253A>T p.K418M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- WDR19 | c.3586T>A p.S1196T | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- XIRP2 | c.1516A>C p.S506R (on ENST00000628543; = p.S681R on NM_152381.6) | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- XKR7 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF248 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF253 | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF429 | c.1611C>A p.Y537* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- ZNF430 | c.1290A>T p.K430N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZNF549 | c.119A>T p.E40V (on ENST00000376233 / NM_001199295.2; = p.E27V on NM_153263.2) | Missense Mutation (SNP) | VAF 87/137 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF658 | c.3140G>T p.R1047I | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.106); called by muse, varscan2
- ZSCAN9 | c.339G>T p.R113S | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- AASS | c.1683T>G p.L561= | Silent (SNP) | VAF 56/157 reads (36%) | called by muse, mutect2, varscan2
- ABCG8 | c.618C>A p.G206= | Silent (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- ADD2 | c.1611G>T p.L537= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as COSV100035113; called by muse, mutect2, varscan2
- AFF2 | c.2520T>A p.A840= | Silent (SNP) | VAF 175/287 reads (61%) | called by muse, mutect2, varscan2
- ARSF | c.1464C>T p.T488= | Silent (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- ATP4A | c.2415C>A p.I805= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV52871137; called by muse, mutect2, varscan2
- B4GALNT2 | c.1176C>A p.T392= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- BEST3 | c.792C>T p.Y264= | Silent (SNP) | VAF 31/217 reads (14%) | catalogued as rs780570896, COSV58306312; called by muse, mutect2, varscan2
- BMP6 | c.1137G>T p.R379= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- C1orf141 | c.915A>T p.T305= | Silent (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- CACNA1C | c.5805C>T p.D1935= (on ENST00000399634 / NM_001167625.1; = p.D1864= on NM_000719.7) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs748240245, COSV59777282; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALHM1 | c.912G>T p.T304= | Silent (SNP) | VAF 11/12 reads (92%) | called by muse, mutect2, varscan2
- CAMK2A | c.309C>A p.A103= | Silent (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- CAV3 | c.267C>A p.G89= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- CCDC97 | c.297G>T p.L99= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs368463774; called by muse, mutect2, varscan2
- CCNB3 | c.2505G>A p.E835= | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- CCT7 | c.171A>C p.T57= | Silent (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- CD40 | c.762T>G p.T254= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs1243468569; called by muse, mutect2, varscan2
- CDH6 | c.2175G>C p.T725= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs994772358, COSV54065021; called by muse, mutect2, varscan2
- CELA1 | c.477G>C p.L159= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- CEMIP | c.210C>A p.A70= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs1033692711; called by muse, mutect2, varscan2
- CLASP2 | c.4494A>C p.A1498= (on ENST00000359576; = p.A1497= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as rs1158209239, COSV56293216; called by muse, mutect2, varscan2
- CNGB3 | c.24C>A p.V8= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as rs1463640274; called by muse, mutect2, varscan2
- COL7A1 | c.6994C>A p.R2332= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as CM031665; called by muse, mutect2, varscan2
- COLEC11 | c.726C>T p.C242= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs200835001, COSV52598204; called by muse, mutect2, varscan2
- CSF3R | c.2058C>A p.P686= | Silent (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- CTNNA3 | c.519C>T p.T173= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs764374345; called by muse, mutect2
- CYGB | c.84G>A p.Q28= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- DCSTAMP | c.192C>T p.S64= | Silent (SNP) | VAF 85/157 reads (54%) | called by muse, mutect2, varscan2
- DDR2 | c.2013C>A p.P671= | Silent (SNP) | VAF 89/274 reads (32%) | called by muse, mutect2, varscan2
- DENND2A | c.2640C>T p.D880= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs780910530; called by mutect2, varscan2
- DGKB | c.885C>T p.I295= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs1332170493; called by muse, mutect2, varscan2
- DNAH9 | c.4524C>G p.V1508= | Silent (SNP) | VAF 61/100 reads (61%) | called by muse, mutect2, varscan2
- ENPP5 | c.1131A>G p.L377= | Silent (SNP) | VAF 142/380 reads (37%) | catalogued as rs780891625; called by muse, mutect2, varscan2
- EPB41L1 | c.1068C>T p.N356= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- ERN2 | c.459C>T p.S153= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs1454879377, COSV56832067; called by muse, mutect2, varscan2
- FAM13A | c.162C>A p.T54= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs767389467; called by muse, mutect2, varscan2
- FAM149A | c.1182T>G p.R394= (on ENST00000356371 / NM_001367768.2; = p.R103= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- FLG | c.3897G>A p.R1299= | Silent (SNP) | VAF 56/216 reads (26%) | called by muse, mutect2, varscan2
- FLG2 | c.2451C>T p.S817= | Silent (SNP) | VAF 80/640 reads (13%) | catalogued as rs201122691, COSV66169536; called by muse, mutect2, varscan2
- FPR1 | c.63C>A p.G21= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs1427994148; called by muse, mutect2, varscan2
- FREM2 | c.9019C>A p.R3007= | Silent (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- FSIP2 | c.18156A>C p.V6052= | Silent (SNP) | VAF 64/375 reads (17%) | called by muse, mutect2, varscan2
- GNG11 | c.221A>G p.*74= | Silent (SNP) | VAF 52/128 reads (41%) | catalogued as rs1333976631; called by muse, mutect2, varscan2
- GPR156 | c.546G>T p.T182= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as COSV59939524; called by muse, mutect2, varscan2
- GRB7 | c.1587G>A p.R529= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- GTSE1 | c.711G>T p.L237= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2
- HS3ST5 | c.60C>T p.A20= | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as rs769961503; called by muse, mutect2, varscan2
- HTR2A | c.300C>T p.S100= | Silent (SNP) | VAF 69/119 reads (58%) | catalogued as COSV101096669; called by muse, mutect2, varscan2
- IGSF1 | c.960C>T p.F320= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as COSV63838484; called by muse, mutect2, varscan2
- IQGAP2 | c.2502G>A p.L834= | Silent (SNP) | VAF 64/106 reads (60%) | called by muse, mutect2, varscan2
- ITPRID1 | c.1395C>A p.S465= | Silent (SNP) | VAF 91/227 reads (40%) | catalogued as rs745451810; called by muse, mutect2, varscan2
- KCND2 | c.1264C>A p.R422= | Silent (SNP) | VAF 131/321 reads (41%) | catalogued as COSV58599466; called by muse, mutect2, varscan2
- KDM4C | c.1290A>G p.E430= | Silent (SNP) | VAF 75/130 reads (58%) | called by muse, mutect2, varscan2
- KDR | c.1515T>C p.A505= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs902907328; called by muse, mutect2, varscan2
- KIAA1549L | c.4077T>A p.S1359= (on ENST00000321505; = p.S1656= on NM_012194.3) | Silent (SNP) | VAF 50/76 reads (66%) | called by muse, mutect2, varscan2
- KIZ | c.594C>T p.A198= | Silent (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
- LHX8 | c.189C>T p.A63= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs531106050; called by muse, mutect2
- LHX8 | c.291C>A p.V97= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- LONRF3 | c.1140T>A p.A380= (on ENST00000371628 / NM_001031855.3; = p.A339= on NM_024778.5) | Silent (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2, varscan2
- LPCAT2 | c.648A>T p.L216= | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- MAGEA10 | c.93C>A p.P31= | Silent (SNP) | VAF 91/134 reads (68%) | catalogued as COSV99726713; called by muse, mutect2, varscan2
- MTCL1 | c.4104C>T p.R1368= (on ENST00000306329 / NM_001378206.1; = p.R1049= on NM_015210.4) | Silent (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- NBEA | c.6507G>T p.G2169= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- NEMP1 | c.654C>T p.Y218= (on ENST00000300128 / NM_001130963.2; = p.Y145= on NM_015257.3) | Silent (SNP) | VAF 43/56 reads (77%) | catalogued as rs1450740723; called by muse, mutect2, varscan2
- NKG7 | c.288C>T p.T96= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs144240268, COSV52468119; called by muse, mutect2, varscan2
- NMD3 | c.1164G>A p.E388= | Silent (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- NPLOC4 | c.240G>T p.S80= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- NRXN1 | c.3864C>A p.I1288= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV60500950; called by muse, mutect2, varscan2
- NXF3 | c.627C>A p.A209= | Silent (SNP) | VAF 186/410 reads (45%) | catalogued as COSV67702585; called by muse, mutect2, varscan2
- OR10J1 | c.714C>T p.A238= | Silent (SNP) | VAF 38/109 reads (35%) | called by muse, mutect2, varscan2
- OR10Q1 | c.462C>A p.G154= | Silent (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- OR2A2 | c.492G>A p.R164= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as rs748696307; called by muse, mutect2, varscan2
- OR2W3 | c.303C>T p.L101= | Silent (SNP) | VAF 34/159 reads (21%) | called by muse, mutect2, varscan2
- OR4S2 | c.630T>A p.V210= | Silent (SNP) | VAF 124/355 reads (35%) | called by muse, mutect2, varscan2
- OR5H1 | c.78C>A p.P26= | Silent (SNP) | VAF 106/317 reads (33%) | catalogued as rs1279545145; called by muse, mutect2, varscan2
- OR6N1 | c.843C>A p.L281= | Silent (SNP) | VAF 266/716 reads (37%) | called by muse, mutect2, varscan2
- P2RY2 | c.471G>T p.V157= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs369653027; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1134G>T p.A378= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- PARP10 | c.1173T>A p.S391= | Silent (SNP) | VAF 104/160 reads (65%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1917C>A p.T639= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV65357157; called by muse, mutect2, varscan2
- PCDHGB4 | c.1641C>T p.R547= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- PHKB | c.264A>G p.L88= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs1167934661, COSV54522667; called by muse, mutect2, varscan2
- PKHD1 | c.1338G>T p.L446= | Silent (SNP) | VAF 77/250 reads (31%) | called by muse, mutect2, varscan2
- POU3F4 | c.678G>T p.V226= | Silent (SNP) | VAF 95/293 reads (32%) | catalogued as COSV64541150; called by muse, mutect2, varscan2
- PRAMEF7 | c.1359C>A p.T453= | Silent (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- RALGPS2 | c.147A>G p.T49= | Silent (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- SIN3B | c.1797G>A p.A599= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs977845961, COSV56132344; called by muse, mutect2, varscan2
- SOX7 | c.957C>T p.S319= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- SRSF9 | c.483C>T p.A161= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs1432820831; called by muse, mutect2, varscan2
- STAB2 | c.1353A>T p.T451= | Silent (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- STT3B | c.831A>T p.V277= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs762127048; called by muse, mutect2, varscan2
- TBX22 | c.369C>T p.P123= | Silent (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- TENM1 | c.714G>A p.T238= | Silent (SNP) | VAF 72/393 reads (18%) | catalogued as rs201701923, COSV64424846, COSV64439965; called by muse, mutect2, varscan2
- TGIF2LX | c.597C>A p.S199= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99383269; called by muse, mutect2, varscan2
- TGM5 | c.1869G>A p.T623= (on ENST00000220420 / NM_201631.4; = p.T541= on NM_004245.4) | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs936743659, COSV99588804; called by muse, mutect2, varscan2
- USH2A | c.5790A>T p.R1930= | Silent (SNP) | VAF 101/304 reads (33%) | called by muse, mutect2, varscan2
- ZBTB3 | c.1312C>A p.R438= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV67360851; called by muse, mutect2, varscan2
- CASTOR3 | n.336T>C | RNA (SNP) | VAF 5/15 reads (33%) | catalogued as rs1283524828; called by muse, mutect2, varscan2
- NR4A3 | c.1254+37C>T | Intron (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- OPRM1 | c.1164+1905C>G | Intron (SNP) | VAF 73/121 reads (60%) | catalogued as COSV57674366; called by muse, mutect2, varscan2
- OR2W5 | n.329G>A | RNA (SNP) | VAF 37/127 reads (29%) | catalogued as rs781076594; called by muse, mutect2, varscan2
- RAB15 | c.324+89C>G | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- SNORD115-38 | n.72C>T | RNA (SNP) | VAF 21/77 reads (27%) | catalogued as rs565650395; called by muse, mutect2, varscan2
- WIPF3 | c.1428+17G>T | Intron (SNP) | VAF 76/191 reads (40%) | called by muse, mutect2, varscan2
